Somatic mutation profile of tumor specimen ALCH-B2X7-TTP1-A (aliquot ALCH-B2X7-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B2X7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.0 years (27,410 days).
Specimen ALCH-B2X7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7f1d805-58d2-4bf7-b3e2-d4db39a881d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2X7-NB1-A (Blood Derived Normal), aliquot ALCH-B2X7-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3099292-d73d-4e26-8139-045d068637ce

The open-access MAF lists 78 somatic variants for this specimen: 53 protein-altering or splice-affecting, 17 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 17, Nonsense Mutation 5, Intron 4, Frame Shift Del 1, 5'UTR 1, RNA 1, 3'Flank 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 226/1054 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.3562C>G p.P1188A | Missense Mutation (SNP) | VAF 19/284 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV52221967; called by muse, mutect2
- ADAMTS8 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 11/205 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57293549; called by muse, mutect2
- ANXA6 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 42/1022 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs545945295, COSV62906173; called by muse, mutect2
- BRD9 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 44/1015 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.696); catalogued as COSV100056814; called by muse, mutect2
- CAMTA1 | c.2945G>A p.R982Q | Missense Mutation (SNP) | VAF 32/549 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs990793983; called by muse, mutect2
- DISP3 | c.160C>T p.R54* | Nonsense Mutation (SNP) | VAF 17/219 reads (8%) | catalogued as COSV53829632; called by muse, mutect2
- EML6 | c.1077G>C p.L359F | Missense Mutation (SNP) | VAF 36/339 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1253969297, COSV100727983; called by muse, mutect2, varscan2
- F2R | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 1066/1880 reads (57%) | SIFT tolerated (0.7); PolyPhen benign (0.011); catalogued as rs1366520771; called by muse, varscan2
- FAM83D | c.625C>A p.L209M | Missense Mutation (SNP) | VAF 38/606 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1403568531; called by muse, mutect2
- GRIK3 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as rs569112734, COSV66144226; called by muse, mutect2, varscan2
- MYLK2 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 38/555 reads (7%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as rs980958977; called by muse, mutect2
- OR51B5 | c.278C>A p.A93E | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV56175716, COSV56177519; called by muse, mutect2
- PKHD1L1 | c.944A>G p.N315S | Missense Mutation (SNP) | VAF 28/650 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as rs1217387111; called by muse, mutect2
- RBM15B | c.1734G>T p.W578C | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100082474; called by muse, mutect2
- STX18 | c.323C>G p.S108* | Nonsense Mutation (SNP) | VAF 22/329 reads (7%) | catalogued as rs776535333; called by muse, mutect2
- WDR87 | c.3527G>A p.R1176H | Missense Mutation (SNP) | VAF 26/352 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.066); catalogued as rs538252815, COSV58192938, COSV58197358; called by muse, mutect2
- ZNF423 | c.2924G>A p.R975H (on ENST00000563137 / NM_001379286.1; = p.R967H on NM_015069.4) | Missense Mutation (SNP) | VAF 19/255 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); catalogued as rs771703239, COSV52190092; called by muse, mutect2
- ZNF484 | c.2128C>T p.H710Y | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775607515; called by muse, mutect2
- ARHGAP17 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- ATP7A | c.912T>A p.Y304* | Nonsense Mutation (SNP) | VAF 29/310 reads (9%) | called by muse, mutect2
- DCAF12L1 | c.664A>T p.M222L | Missense Mutation (SNP) | VAF 13/243 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- DNAH5 | c.1361A>T p.K454I | Missense Mutation (SNP) | VAF 19/523 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.039); called by muse, mutect2
- EIF3F | c.289G>T p.V97F | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- HAL | c.1875G>A p.M625I | Missense Mutation (SNP) | VAF 41/627 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- HMGXB3 | c.1204del p.M402Cfs*61 (on ENST00000613459; = p.M156Cfs*61 on NM_014983.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 197/791 reads (25%) | called by mutect2, pindel, varscan2
- HTT | c.7705G>A p.A2569T | Missense Mutation (SNP) | VAF 20/538 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.218); called by muse, mutect2
- IL1RAPL2 | c.617A>C p.E206A | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.492); called by muse, mutect2
- ITGB1 | c.1238G>C p.R413T | Missense Mutation (SNP) | VAF 30/322 reads (9%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); called by muse, mutect2
- KMT2D | c.5327T>C p.F1776S | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KMT2D | c.5326T>G p.F1776V | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MSRB3 | c.439G>C p.D147H | Missense Mutation (SNP) | VAF 50/1361 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- MT2A | c.28+5G>C | Splice Region (SNP) | VAF 31/502 reads (6%) | called by muse, mutect2
- MYH14 | c.438C>A p.N146K | Missense Mutation (SNP) | VAF 23/767 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NEK11 | c.714A>T p.L238F | Missense Mutation (SNP) | VAF 27/252 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- POLG | c.3664C>T p.Q1222* | Nonsense Mutation (SNP) | VAF 33/866 reads (4%) | called by muse, mutect2
- PRDM2 | c.1407T>G p.N469K | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PREX2 | c.201A>C p.E67D | Missense Mutation (SNP) | VAF 30/692 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.932); called by muse, mutect2
- PRMT3 | c.926T>C p.I309T | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by mutect2, varscan2
- PRPS1L1 | c.328A>G p.K110E | Missense Mutation (SNP) | VAF 31/562 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- PRRC2C | c.4232T>G p.F1411C (on ENST00000367742; = p.F1409C on NM_015172.4) | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); called by muse, mutect2
- RAG2 | c.136T>G p.F46V | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- RAN | c.293A>G p.Y98C | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2
- RAPH1 | c.783G>C p.E261D (on ENST00000319170 / NM_213589.3; = p.E313D on NM_203365.4) | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2
- SLC2A13 | c.721A>T p.M241L | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2
- SPATA5 | c.2168T>G p.I723S | Missense Mutation (SNP) | VAF 19/417 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SRPX | c.1111C>G p.L371V | Missense Mutation (SNP) | VAF 20/436 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- STON2 | c.1232G>T p.S411I (on ENST00000649389 / NM_001366849.2; = p.S354I on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/674 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.681); called by muse, mutect2
- TATDN2 | c.1022C>T p.T341I | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.02); called by muse, mutect2
- TMEM41A | c.307C>G p.L103V | Missense Mutation (SNP) | VAF 16/299 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.034); called by muse, mutect2
- VEZF1 | c.818A>C p.K273T | Missense Mutation (SNP) | VAF 22/629 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2
- ZNF512B | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- ZNF628 | c.1210C>T p.H404Y | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- CATSPERB | c.2484C>T p.S828= | Silent (SNP) | VAF 47/580 reads (8%) | called by muse, mutect2
- CORO7 | c.2406G>T p.R802= | Silent (SNP) | VAF 9/160 reads (6%) | catalogued as rs753438532; called by muse, mutect2
- EPHA6 | c.2490T>A p.S830= (on ENST00000389672 / NM_001080448.3; = p.S222= on NM_173655.4) | Silent (SNP) | VAF 7/115 reads (6%) | called by muse, mutect2
- F2R | c.477C>T p.I159= | Silent (SNP) | VAF 768/1338 reads (57%) | called by muse, mutect2, varscan2
- F2R | c.1065C>T p.L355= | Silent (SNP) | VAF 510/896 reads (57%) | called by mutect2, varscan2
- GPD2 | c.267C>T p.V89= | Silent (SNP) | VAF 24/699 reads (3%) | called by muse, mutect2
- HELLS | c.2049G>C p.L683= | Silent (SNP) | VAF 54/636 reads (8%) | called by muse, mutect2
- ITGA3 | c.708G>A p.E236= | Silent (SNP) | VAF 22/444 reads (5%) | called by muse, mutect2
- MARK4 | c.441C>T p.L147= | Silent (SNP) | VAF 22/341 reads (6%) | catalogued as rs565217769, COSV53461352; called by muse, mutect2
- NKAIN3 | c.456C>G p.V152= | Silent (SNP) | VAF 40/116 reads (34%) | called by mutect2, varscan2
- OCA2 | c.2271C>T p.H757= | Silent (SNP) | VAF 50/1041 reads (5%) | catalogued as rs148894313; called by muse, mutect2
- OTOF | c.1824A>G p.E608= | Silent (SNP) | VAF 27/713 reads (4%) | called by muse, mutect2
- PCDHA1 | c.1032T>C p.N344= | Silent (SNP) | VAF 18/165 reads (11%) | catalogued as COSV65372750; called by muse, mutect2, varscan2
- PLS1 | c.867C>T p.S289= | Silent (SNP) | VAF 28/260 reads (11%) | called by muse, mutect2, varscan2
- SMG8 | c.2883G>A p.V961= | Silent (SNP) | VAF 27/428 reads (6%) | called by muse, mutect2
- SPTBN5 | c.10080G>C p.G3360= | Silent (SNP) | VAF 17/228 reads (7%) | called by muse, mutect2
- SSR1 | c.9C>G p.L3= | Silent (SNP) | VAF 13/200 reads (7%) | called by muse, mutect2
- BMERB1 | chr16:15591104 A>G | 3'Flank (SNP) | VAF 36/536 reads (7%) | called by muse, mutect2
- CLCN2 | c.2217+20C>G | Intron (SNP) | VAF 18/194 reads (9%) | called by muse, mutect2
- DDO | c.-23A>G | 5'UTR (SNP) | VAF 26/350 reads (7%) | catalogued as rs574664686; called by muse, mutect2
- NHSL2 | chrX:72132096 C>A | 5'Flank (SNP) | VAF 64/744 reads (9%) | called by muse, mutect2
- QDPR | c.437-11C>G | Intron (SNP) | VAF 42/522 reads (8%) | called by muse, mutect2
- RGPD1 | c.48+5864T>C | Intron (SNP) | VAF 50/778 reads (6%) | catalogued as COSV67963088; called by muse, mutect2
- SSPOP | n.14620G>C | RNA (SNP) | VAF 9/103 reads (9%) | called by muse, mutect2
- YIF1B | c.58+111G>A | Intron (SNP) | VAF 32/344 reads (9%) | catalogued as rs1442571641; called by muse, mutect2
